Gene-level copy-number profile of tumor specimen TCGA-02-0326-01A from TCGA case TCGA-02-0326, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 82.6 years (30,160 days).
Specimen TCGA-02-0326-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.ceea5052-baad-4293-9937-ad39ddefaf56.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 4,962 have no estimate.
https://portal.gdc.cancer.gov/files/da7f7ced-2501-4620-8e77-028f0dfb29e9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 1,442; copy number 2: 51,155; copy number 3: 2,985; copy number 4: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0326-01): tumor purity 0.52, ploidy 2.04, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,789,179–19,967,994, 5 genes: AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3.
- chr9:20,341,669–22,128,103, 62 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,442. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
